Somatic mutation profile of tumor specimen CDDP-ACPV-TTP1-A (aliquot CDDP-ACPV-TTP1-A-2-0-D-A572-36) from CDDP_EAGLE case CDDP-ACPV, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 63 years.
Specimen CDDP-ACPV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0385cadd-35ce-47e9-9c71-2ec240ac8d20.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ACPV-NB1-A (Blood Derived Normal), aliquot CDDP-ACPV-NB1-A-1-0-D-A572-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74d0f651-cb32-41aa-b3ab-a18a8334be49

The open-access MAF lists 134 somatic variants for this specimen: 86 protein-altering or splice-affecting, 21 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 21, Intron 11, Frame Shift Ins 4, 3'UTR 4, 5'UTR 4, Nonsense Mutation 4, Splice Region 3, 5'Flank 3, Splice Site 3, RNA 3, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 62/213 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANKS1B | c.2370A>G p.I790M | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61353409; called by muse, mutect2, varscan2
- ARHGAP25 | c.1439G>T p.G480V (on ENST00000409202 / NM_001007231.3; = p.G472V on NM_014882.3) | Missense Mutation (SNP) | VAF 54/220 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.439); catalogued as COSV54910980; called by muse, mutect2, varscan2
- ATM | c.7654C>G p.H2552D | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53769093; called by muse, mutect2, varscan2
- BVES | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as COSV58947380, COSV58950329; called by muse, mutect2, varscan2
- CCDC136 | c.2145G>C p.R715S | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV52805396; called by muse, mutect2, varscan2
- CETP | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 82/309 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs984216604, COSV52364286; called by muse, mutect2, varscan2
- CFAP47 | c.1372G>T p.D458Y | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.197); catalogued as COSV52886630; called by muse, mutect2, varscan2
- DPYSL5 | c.763G>T p.D255Y | Missense Mutation (SNP) | VAF 74/351 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV56509684; called by muse, mutect2, varscan2
- DSCAM | c.5783G>T p.C1928F | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.168); catalogued as COSV68027723; called by muse, mutect2, varscan2
- EXT1 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 97/574 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as CM132219; called by muse, mutect2, varscan2
- GABRA4 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755003245, COSV51925014; called by muse, mutect2, varscan2
- GGA2 | c.1108C>T p.H370Y | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as rs1219812595; called by muse, mutect2, varscan2
- JAZF1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 37/108 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.14); catalogued as COSV52248706; called by muse, mutect2, varscan2
- LCE1F | c.155G>T p.C52F | Missense Mutation (SNP) | VAF 49/288 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.158); catalogued as COSV57669888; called by muse, mutect2, varscan2
- MYH3 | c.1880C>T p.T627M | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs370119974; called by muse, mutect2, varscan2
- NPHS1 | c.1316A>T p.Y439F | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as CM156492; called by muse, mutect2, varscan2
- NTRK3 | c.454C>A p.L152I | Missense Mutation (SNP) | VAF 75/347 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.291); catalogued as COSV58111010, COSV58121241; called by muse, mutect2, varscan2
- OR5T1 | c.511C>G p.H171D | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV100478753; called by muse, mutect2
- PCDHB5 | c.1375G>T p.V459F | Missense Mutation (SNP) | VAF 74/448 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs781824741; called by muse, mutect2, varscan2
- PHF8 | c.370G>A p.V124I (on ENST00000357988 / NM_001184896.1; = p.V88I on NM_015107.3) | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199664796; called by muse, mutect2, varscan2
- RAB18 | c.343A>G p.I115V | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs765906124; called by mutect2, varscan2
- RBM10 | c.2218G>T p.E740* | Nonsense Mutation (SNP) | VAF 14/30 reads (47%) | catalogued as COSV61309228; called by muse, mutect2
- RGPD4 | c.1573T>C p.C525R | Missense Mutation (SNP) | VAF 38/464 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs1376240007; called by muse, mutect2
- RXFP2 | c.1201C>A p.P401T | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53640853; called by muse, mutect2, varscan2
- SETBP1 | c.1925C>A p.P642H | Missense Mutation (SNP) | VAF 92/456 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs1408306200; called by muse, mutect2, varscan2
- SLC6A18 | c.1418A>G p.N473S | Missense Mutation (SNP) | VAF 64/310 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1329936351; called by muse, mutect2, varscan2
- SNX31 | c.626C>A p.S209Y | Missense Mutation (SNP) | VAF 71/224 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV61264965; called by muse, mutect2, varscan2
- STPG2 | c.513G>T p.E171D | Missense Mutation (SNP) | VAF 16/150 reads (11%) | catalogued as rs971265893; called by muse, mutect2, varscan2
- TECRL | c.657+1G>A p.X219_splice | Splice Site (SNP) | VAF 39/241 reads (16%) | catalogued as COSV101168906; called by muse, mutect2, varscan2
- VCAN | c.5120G>A p.S1707N | Missense Mutation (SNP) | VAF 73/338 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.15); catalogued as COSV54114679; called by muse, mutect2, varscan2
- ABCA4 | c.6006T>C p.S2002= | Splice Region (SNP) | VAF 23/91 reads (25%) | called by muse, mutect2, varscan2
- ADAD1 | c.445G>T p.E149* | Nonsense Mutation (SNP) | VAF 36/154 reads (23%) | called by muse, mutect2, varscan2
- ADGRG2 | c.306C>A p.G102= (on ENST00000379869 / NM_001079858.3; = p.G99= on NM_005756.4) | Splice Region (SNP) | VAF 41/107 reads (38%) | called by muse, mutect2, varscan2
- ANK2 | c.1291G>A p.G431S | Missense Mutation (SNP) | VAF 81/440 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANK2 | c.9232A>G p.T3078A | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANKRD50 | c.2671G>T p.G891C | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARSF | c.851T>A p.L284H | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATRNL1 | c.3106A>T p.T1036S | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- BPIFC | c.1289C>A p.S430Y | Missense Mutation (SNP) | VAF 73/312 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- CACNA1H | c.4930-1G>T p.X1644_splice | Splice Site (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- CCL4L2 | c.53G>A p.C18Y | Missense Mutation (SNP) | VAF 48/272 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- CFHR2 | c.340dup p.C114Lfs*11 | Frame Shift Ins (INS) | VAF 69/367 reads (19%) | called by mutect2, varscan2
- COL11A2 | c.1360-1G>T p.X454_splice (on ENST00000341947 / NM_080680.3; = p.X347_splice on NM_080679.2) | Splice Site (SNP) | VAF 96/367 reads (26%) | called by muse, mutect2, varscan2
- CPXM1 | c.755T>C p.I252T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- CRYBG2 | c.98A>T p.K33I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- DCAF8L1 | c.925G>T p.A309S | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- DCDC2C | c.620del p.G207Dfs*73 | Frame Shift Del (DEL) | VAF 46/196 reads (23%) | called by mutect2, pindel, varscan2
- DEFB112 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DNAH9 | c.11176C>G p.R3726G | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DSCAM | c.2492A>T p.E831V | Missense Mutation (SNP) | VAF 38/215 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.322); called by muse, varscan2
- F5 | c.400C>A p.P134T | Missense Mutation (SNP) | VAF 93/240 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- FAT4 | c.6279G>T p.L2093F | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- FZD10 | c.1618A>T p.K540* | Nonsense Mutation (SNP) | VAF 14/132 reads (11%) | called by mutect2, varscan2
- GRM6 | c.1591G>T p.V531L | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- HBE1 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 59/204 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HIVEP2 | c.4717G>T p.E1573* | Nonsense Mutation (SNP) | VAF 34/196 reads (17%) | called by muse, mutect2, varscan2
- IDE | c.2656A>T p.I886F | Missense Mutation (SNP) | VAF 32/275 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- IGDCC3 | c.877A>G p.I293V | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.326); called by mutect2, varscan2
- IGLL1 | c.199dup p.W67Lfs*26 | Frame Shift Ins (INS) | VAF 12/65 reads (18%) | called by mutect2, pindel, varscan2
- ITPRID2 | c.2045C>G p.T682S | Missense Mutation (SNP) | VAF 36/220 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KDM2A | c.1450G>T p.D484Y | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by mutect2, varscan2
- KRTAP9-3 | c.256T>A p.C86S | Missense Mutation (SNP) | VAF 21/323 reads (7%) | SIFT tolerated (0.11); called by muse, mutect2
- LMNTD1 | c.775T>A p.W259R | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRFN1 | c.1972dup p.T658Nfs*302 | Frame Shift Ins (INS) | VAF 9/59 reads (15%) | called by mutect2, pindel, varscan2
- MRGPRE | c.538G>T p.V180L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLGN4X | c.1511C>G p.P504R | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- NOD2 | c.2354T>C p.V785A | Missense Mutation (SNP) | VAF 94/360 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NVL | c.186A>G p.V62= | Splice Region (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- OR2G3 | c.498delinsTT p.L166Ffs*8 | Frame Shift Ins (INS) | VAF 19/169 reads (11%) | called by pindel, varscan2*
- PASK | c.2893A>T p.S965C | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- PAX8 | c.410A>G p.Q137R | Missense Mutation (SNP) | VAF 93/430 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- PDZRN3 | c.1211G>A p.G404E | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2
- PIP4P2 | c.710G>A p.C237Y | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PLK1 | c.247A>T p.I83F | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by mutect2, varscan2
- RHBDF1 | c.132G>T p.Q44H | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- RPL4 | c.565A>G p.M189V | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- SHISA7 | c.242T>A p.L81H | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- SLC12A3 | c.2851G>T p.V951F (on ENST00000563236 / NM_001126108.2; = p.V960F on NM_000339.3) | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by mutect2, varscan2
- SLC8A3 | c.1004T>A p.L335Q | Missense Mutation (SNP) | VAF 28/338 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLITRK1 | c.778T>A p.L260M | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.762); called by muse, varscan2
- STK11 | c.157del p.D53Tfs*11 | Frame Shift Del (DEL) | VAF 38/199 reads (19%) | called by pindel, varscan2*
- TP53BP2 | c.2758G>C p.E920Q (on ENST00000343537 / NM_001031685.3; = p.E791Q on NM_005426.2) | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- TRMT12 | c.983A>G p.D328G | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.112); called by muse, mutect2
- WDR47 | c.220A>C p.M74L | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF671 | c.1231A>T p.T411S | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ALPK3 | c.2692C>T p.L898= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV99360050; called by muse, mutect2, varscan2
- CEMP1 | c.138G>A p.Q46= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV53550576; called by muse, mutect2, varscan2
- CTDSP2 | c.660T>A p.P220= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as COSV66079899; called by muse, mutect2, varscan2
- DGKH | c.468A>T p.V156= | Silent (SNP) | VAF 50/155 reads (32%) | called by muse, mutect2, varscan2
- DNAJB1 | c.561C>T p.H187= | Silent (SNP) | VAF 20/264 reads (8%) | called by muse, mutect2
- DSG1 | c.2499T>A p.G833= | Silent (SNP) | VAF 38/256 reads (15%) | called by muse, mutect2, varscan2
- EMC1 | c.873C>T p.F291= | Silent (SNP) | VAF 24/143 reads (17%) | called by muse, mutect2, varscan2
- HDAC2 | c.672T>A p.A224= | Silent (SNP) | VAF 14/132 reads (11%) | called by muse, mutect2, varscan2
- HTT | c.4032C>T p.R1344= | Silent (SNP) | VAF 46/272 reads (17%) | catalogued as rs1560579107; called by muse, mutect2, varscan2
- KRT82 | c.858C>T p.D286= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as rs750739044, COSV57787124; called by mutect2, varscan2
- MTARC1 | c.960G>T p.L320= | Silent (SNP) | VAF 29/347 reads (8%) | catalogued as COSV100856338; called by muse, mutect2
- MYH15 | c.1680C>T p.F560= | Silent (SNP) | VAF 26/173 reads (15%) | catalogued as COSV99843691; called by muse, mutect2, varscan2
- POLG2 | c.1137C>T p.A379= | Silent (SNP) | VAF 41/163 reads (25%) | catalogued as rs1159659072, COSV101604425; called by muse, mutect2, varscan2
- REC114 | c.792G>A p.L264= | Silent (SNP) | VAF 34/152 reads (22%) | catalogued as rs779886364, COSV58525164; called by muse, mutect2, varscan2
- SNX31 | c.627C>A p.S209= | Silent (SNP) | VAF 74/231 reads (32%) | catalogued as COSV61263835; called by muse, mutect2, varscan2
- SPTA1 | c.5208G>C p.V1736= | Silent (SNP) | VAF 69/370 reads (19%) | catalogued as COSV100935200; called by muse, mutect2, varscan2
- TLL2 | c.1224C>T p.Y408= | Silent (SNP) | VAF 60/203 reads (30%) | catalogued as rs781461065, COSV63573907; called by muse, mutect2, varscan2
- TRIML2 | c.408G>T p.L136= | Silent (SNP) | VAF 26/146 reads (18%) | catalogued as COSV100456163; called by muse, varscan2
- TTC25 | c.321C>G p.G107= | Silent (SNP) | VAF 50/278 reads (18%) | called by muse, mutect2, varscan2
- ZDHHC7 | c.66C>T p.N22= | Silent (SNP) | VAF 12/98 reads (12%) | called by muse, mutect2
- ZNF423 | c.1344C>T p.S448= (on ENST00000563137 / NM_001379286.1; = p.S440= on NM_015069.4) | Silent (SNP) | VAF 26/94 reads (28%) | called by muse, mutect2, varscan2
- ABRAXAS1 | c.178+1819A>C | Intron (SNP) | VAF 9/102 reads (9%) | called by mutect2, varscan2
- AOX3P | chr2:200676892 G>A | 5'Flank (SNP) | VAF 34/190 reads (18%) | called by muse, mutect2, varscan2
- ARFGAP3 | chr22:42858434 G>A | 5'Flank (SNP) | VAF 20/290 reads (7%) | catalogued as rs1251867768; called by muse, mutect2
- CNTNAP3P2 | n.1227G>T | RNA (SNP) | VAF 54/163 reads (33%) | called by muse, mutect2, varscan2
- FAM161A | c.*618A>G | 3'UTR (SNP) | VAF 8/72 reads (11%) | catalogued as rs980814053; called by mutect2, varscan2
- FAM161A | c.*555T>C | 3'UTR (SNP) | VAF 23/199 reads (12%) | catalogued as rs1195163165; called by muse, varscan2
- GALNT13 | c.1396-919A>G | Intron (SNP) | VAF 12/86 reads (14%) | called by muse, varscan2
- GRM7 | c.-154A>T | 5'UTR (SNP) | VAF 22/186 reads (12%) | called by mutect2, varscan2
- LINC00632 | n.104+2061C>G | Intron (SNP) | VAF 14/151 reads (9%) | called by muse, mutect2
- MARCHF1 | c.-322-85534G>T | Intron (SNP) | VAF 10/84 reads (12%) | called by muse, varscan2
- MYH6 | c.-4C>T | 5'UTR (SNP) | VAF 46/160 reads (29%) | called by muse, mutect2, varscan2
- NXF5 | n.1050C>A | RNA (SNP) | VAF 21/116 reads (18%) | called by muse, mutect2, varscan2
- NXF5 | n.1049C>A | RNA (SNP) | VAF 21/117 reads (18%) | called by muse, mutect2, varscan2
- PGA5 | c.657-75T>A | Intron (SNP) | VAF 96/445 reads (22%) | called by muse, mutect2, varscan2
- POLQ | c.-67del | 5'UTR (DEL) | VAF 12/55 reads (22%) | catalogued as COSV99952422; called by mutect2, pindel, varscan2
- PRDM11 | chr11:45226948 G>T | 3'Flank (SNP) | VAF 61/181 reads (34%) | called by muse, mutect2, varscan2
- RAB3GAP1 | c.151-1164G>T | Intron (SNP) | VAF 17/132 reads (13%) | called by muse, varscan2
- RFX7 | c.*5901del | 3'UTR (DEL) | VAF 20/191 reads (10%) | called by mutect2, pindel, varscan2
- RNU6-1191P | chr16:81109244 C>G | 5'Flank (SNP) | VAF 47/192 reads (24%) | called by muse, mutect2, varscan2
- RTBDN | c.462+330T>C | Intron (SNP) | VAF 6/24 reads (25%) | catalogued as rs1426165164; called by mutect2, varscan2
- SLC4A8 | c.2172+4996A>G | Intron (SNP) | VAF 16/160 reads (10%) | called by muse, mutect2
- SPOCD1 | c.2534+96G>A | Intron (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2, varscan2
- TM7SF3 | c.91+1322G>A | Intron (SNP) | VAF 7/64 reads (11%) | catalogued as rs966894940, COSV104420657; called by mutect2, varscan2
- USP4 | c.696-901T>C | Intron (SNP) | VAF 14/152 reads (9%) | catalogued as rs1227647101, COSV55535256; called by muse, mutect2
- VMP1 | c.*1389G>C | 3'UTR (SNP) | VAF 71/300 reads (24%) | called by muse, mutect2, varscan2
- ZNF667 | c.-23G>T | 5'UTR (SNP) | VAF 40/220 reads (18%) | called by muse, varscan2
- ZNF843 | chr16:31434866 C>G | 3'Flank (SNP) | VAF 8/108 reads (7%) | catalogued as rs1477227692; called by muse, mutect2
